Surgical pathology report (de-identified scan), TCGA case TCGA-49-4506, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4506-01A (Primary Tumor).

[REDACTED]

FINAL DIAGNOSIS ----- Pathologist [REDACTED] [REDACTED] [REDACTED]

LYMPH NODE, AP WINDOW (EXCISION): HYALINIZED INACTIVE
XANULOMAS. NEGATIVE FOR TUMOR.

RIB (EXCISION): PORTION OF UNREMARKABLE RIB. (GROSS DIAGNOSIS
ONLY).

LYMPH NODE, STATION 5 (EXCISION): ONE LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

LYMPH NODE, STATION 7 (EXCISION): FIBROADIPOSE AND FIBROUS
CONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PERIAORTIC TISSUE (EXCISION): ONE LYMPH NODE, NEGATIVE FOR
TUMOR.

LYMPH NODE, L11 (EXCISION): ONE LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

[REDACTED]

Source: NCI Genomic Data Commons file 139aa736-b0bd-4642-bf93-14e95e24b0db (TCGA-49-4506.09FB40CF-AFB5-4DD5-A1B6-6261EF27B65E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).